CCDI case PBCGLZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/78b8bd9e-c7ee-491d-8bfe-28e73b8f4a65

Demographics
Sex at birth: male.

Diagnoses (1)
1. Neoplasm, metastatic: ICD-O-3 morphology code: 8000/6; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 0.4 years (161 days).

Biospecimens (3 samples)
- Sample 0DRO3K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DS9ZV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSI9E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
